Somatic mutation profile of tumor specimen MMRF_2449_1_BM_CD138pos (aliquot MMRF_2449_1_BM_CD138pos_T1_KHS5U_L11615) from MMRF case MMRF_2449, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.2 years (20,529 days).
Specimen MMRF_2449_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d93fb317-1ac4-4620-b54b-097ffe86308a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2449_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2449_1_PB_Whole_C3_KHS5U_L11616; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2961ca76-ec77-4310-8e8f-6a11f8115296

The open-access MAF lists 158 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 47, Silent 21, Intron 18, 3'Flank 6, 5'Flank 4, Nonsense Mutation 3, 5'UTR 3, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6649G>A p.A2217T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as rs1019645340; called by muse, mutect2, varscan2
- DCAF12L1 | c.1250G>T p.W417L | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64422012; called by muse, mutect2, varscan2
- FAM155B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as rs1468525373, COSV52935229; called by muse, mutect2, varscan2
- FAT1 | c.10943C>A p.A3648D | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.915); catalogued as COSV71676166; called by muse, mutect2
- FOXL2 | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 63/82 reads (77%) | catalogued as COSV57731629; called by muse, mutect2, varscan2
- GRM7 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 243/368 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768643294; called by muse, mutect2, varscan2
- IGLV3-1 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145290417; called by muse, varscan2
- IGLV3-1 | c.188T>A p.V63E | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs371127663; called by muse, varscan2
- IGLV4-3 | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs760596970; called by muse, mutect2, varscan2
- IGLV4-60 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 105/156 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV66503704; called by muse, mutect2, varscan2
- ITIH2 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs200935424, COSV64431976; called by muse, mutect2, varscan2
- JARID2 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as rs778012192, COSV59190937; called by muse, mutect2, varscan2
- KRT28 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60683805, COSV60684681; called by muse, mutect2, varscan2
- MICAL2 | c.5839G>A p.V1947I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs537751154, COSV56287396; called by muse, mutect2
- MMP28 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs746307365; called by muse, mutect2, varscan2
- NARF | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 126/240 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1286923896; called by muse, mutect2, varscan2
- PLOD1 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs773170096, COSV52149072; called by muse, mutect2, varscan2
- STAB1 | c.4141G>A p.G1381R | Missense Mutation (SNP) | VAF 149/234 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs753143636; called by muse, mutect2, varscan2
- UBA7 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV61092666; called by muse, mutect2
- UTRN | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140612467; called by muse, mutect2, varscan2
- WDR13 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782291105, COSV54331612; called by muse, mutect2, varscan2
- ZFPM2 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs1327419184; called by muse, mutect2
- ZNF827 | c.1883T>C p.V628A | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65225263; called by muse, mutect2, varscan2
- ABCC9 | c.2038T>C p.S680P | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- AKAP4 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- B3GALT5 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA1G | c.5381C>A p.T1794N | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CLOCK | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COBL | c.1961G>T p.C654F | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CUX2 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- IGHV1-69D | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 144/148 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, varscan2
- IKBKE | c.701+2T>A p.X234_splice | Splice Site (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3939C>G p.N1313K | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KALRN | c.5332C>T p.L1778F (on ENST00000360013 / NM_001024660.4; = p.L81F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2
- KDM2A | c.802A>T p.I268F | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO10 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- NAPA | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NOX5 | c.105T>A p.F35L | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PAK3 | c.1362T>A p.Y454* (on ENST00000262836 / NM_001324328.2; = p.Y439* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 75/154 reads (49%) | called by muse, mutect2, varscan2
- PDZD2 | c.4451G>A p.R1484K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLA2G2C | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1CB | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PRKCD | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN4 | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB3D | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAB7A | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.477C>G p.Y159* | Nonsense Mutation (SNP) | VAF 93/103 reads (90%) | called by muse, mutect2, varscan2
- SAP130 | c.2108A>C p.N703T | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); called by muse, mutect2
- SETDB1 | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SIPA1L2 | c.338T>A p.V113D | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- STOX2 | c.2773A>T p.S925C | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TAPBPL | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- THEM4 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN1 | c.675T>A p.N225K | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TNRC6A | c.5764C>T p.P1922S | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2
- TRBV4-1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 193/370 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZCCHC24 | c.594C>G p.N198K | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRB1 | c.2724C>T p.G908= | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- CASZ1 | c.3804G>A p.K1268= | Silent (SNP) | VAF 71/143 reads (50%) | catalogued as rs776839311; called by muse, mutect2, varscan2
- CCL16 | c.309G>A p.T103= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs200456787; called by muse, mutect2, varscan2
- CENPK | c.324G>A p.L108= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- CNTN1 | c.642C>T p.S214= | Silent (SNP) | VAF 154/286 reads (54%) | called by muse, mutect2, varscan2
- DLG3 | c.1542G>C p.R514= (on ENST00000374360 / NM_021120.4; = p.R177= on NM_020730.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99530049; called by muse, mutect2, varscan2
- DOCK1 | c.2550C>T p.F850= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- ELANE | c.15C>A p.R5= | Silent (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2, varscan2
- FAT1 | c.10944C>A p.A3648= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- IGLV4-3 | c.87A>T p.A29= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as rs564613783; called by muse, mutect2, varscan2
- IL17RC | c.1623C>G p.L541= (on ENST00000295981 / NM_153461.4; = p.L455= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV55973529; called by muse, mutect2, varscan2
- ME3 | c.666G>A p.Q222= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as rs1190741503; called by muse, mutect2, varscan2
- MRPL58 | c.108C>T p.G36= | Silent (SNP) | VAF 99/243 reads (41%) | called by muse, mutect2, varscan2
- NEB | c.5434A>C p.R1812= | Silent (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1668G>C p.L556= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- PPM1J | c.1431C>G p.G477= | Silent (SNP) | VAF 43/47 reads (91%) | catalogued as COSV53518871; called by muse, mutect2, varscan2
- SHROOM2 | c.2676T>A p.S892= | Silent (SNP) | VAF 84/174 reads (48%) | called by muse, mutect2, varscan2
- SPAG11B | c.177A>G p.K59= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1208755220; called by mutect2, varscan2
- UGT2A2 | c.304C>T p.L102= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs981454948, COSV99683758; called by muse, mutect2, varscan2
- USF3 | c.5550A>G p.P1850= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as rs560903823; called by muse, mutect2, varscan2
- ZNF366 | c.1491C>T p.I497= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs367938255; called by muse, mutect2, varscan2
- ADCY1 | c.*967C>A | 3'UTR (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071224 T>G | 3'Flank (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852164 A>C | 3'Flank (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1354-50del | Intron (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.*7698T>C | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*1937G>A | 3'UTR (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- ASCC3 | c.*173G>C | 3'UTR (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- ATP1B1 | c.*256del | 3'UTR (DEL) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- BLMH | c.802-76G>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- C2orf72 | c.*482G>T | 3'UTR (SNP) | VAF 52/91 reads (57%) | called by muse, mutect2, varscan2
- CBL | c.*4751G>A | 3'UTR (SNP) | VAF 55/116 reads (47%) | catalogued as rs1372379294; called by muse, mutect2, varscan2
- CCNY | c.*853C>G | 3'UTR (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65882930 A>T | 3'Flank (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- CLDND1 | c.403+82_403+86del | Intron (DEL) | VAF 44/136 reads (32%) | called by mutect2, pindel, varscan2
- CNOT2 | c.*50G>T | 3'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- CNTN1 | c.2981-8195G>A | Intron (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- COBLL1 | c.*1897G>C | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- DHDDS | c.*1840G>C | 3'UTR (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- DLG1 | c.483+10656C>G | Intron (SNP) | VAF 85/231 reads (37%) | catalogued as COSV58381089; called by muse, mutect2, varscan2
- DTX1 | c.-471C>G | 5'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- FAM216B | c.*2669A>G | 3'UTR (SNP) | VAF 26/27 reads (96%) | called by muse, mutect2, varscan2
- FANCA | c.3626+156G>A | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- FOXK1 | c.*6552G>A | 3'UTR (SNP) | VAF 51/110 reads (46%) | catalogued as rs979715559; called by muse, mutect2, varscan2
- GABRB3 | c.*939dup | 3'UTR (INS) | VAF 48/127 reads (38%) | called by mutect2, pindel, varscan2
- GFAP | chr17:44903779 C>T | 3'Flank (SNP) | VAF 28/76 reads (37%) | catalogued as rs1241270791; called by muse, mutect2, varscan2
- GRM6 | c.*1086G>A | 3'UTR (SNP) | VAF 43/70 reads (61%) | catalogued as rs190418823; called by muse, mutect2, varscan2
- GSN-AS1 | n.59G>T | RNA (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- H2BC9 | c.*171G>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | catalogued as COSV62655865; called by muse, mutect2
- HGF | c.*3475G>T | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*3773C>G | 3'UTR (SNP) | VAF 89/97 reads (92%) | called by muse, mutect2, varscan2
- HMBS | c.160+69T>C | Intron (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- INSYN2A | c.*628A>G | 3'UTR (SNP) | VAF 21/64 reads (33%) | catalogued as rs1303896508; called by muse, mutect2, varscan2
- JPH3 | c.*1121A>G | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- KCNAB2 | c.326+38G>A | Intron (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- KIAA1143 | c.*4021G>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- LCORL | c.*2133C>A | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- LINC02877 | n.567C>G | RNA (SNP) | VAF 25/534 reads (5%) | called by muse, mutect2
- LRGUK | c.*282del | 3'UTR (DEL) | VAF 8/35 reads (23%) | catalogued as rs908409876; called by mutect2, varscan2
- LUM | c.*1512T>G | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as rs1401970047; called by muse, mutect2, varscan2
- METAP1D | chr2:171999786 T>C | 5'Flank (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- MFSD8 | c.-75-57T>G | Intron (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851123 T>A | 5'Flank (SNP) | VAF 134/143 reads (94%) | catalogued as rs562053532; called by muse, mutect2, varscan2
- MME | c.*871A>G | 3'UTR (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- MUC15 | c.*1461T>C | 3'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- MUSK | c.*146A>T | 3'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- MYO1E | c.-93A>G | 5'UTR (SNP) | VAF 70/133 reads (53%) | catalogued as rs974222372; called by muse, mutect2, varscan2
- NDUFS2 | c.95+132C>G | Intron (SNP) | VAF 17/34 reads (50%) | catalogued as COSV63488155; called by muse, mutect2, varscan2
- NDUFS7 | chr19:1383581 G>A | 5'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NEBL | c.*4505C>T | 3'UTR (SNP) | VAF 70/159 reads (44%) | catalogued as rs1033147570; called by muse, mutect2, varscan2
- NFATC3 | c.*1110T>A | 3'UTR (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- NLRX1 | c.2354+50T>A | Intron (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- NSMF | c.1048-77T>A | Intron (SNP) | VAF 64/97 reads (66%) | called by muse, mutect2, varscan2
- NTRK3 | c.*13498C>A | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- PAX7 | c.*1968G>A | 3'UTR (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2
- PDE3A | c.*1878G>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*58C>T | 3'UTR (SNP) | VAF 18/39 reads (46%) | catalogued as rs1046324287; called by muse, mutect2, varscan2
- PLK2 | c.271-52C>A | Intron (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- PLXDC2 | c.-494A>T | 5'UTR (SNP) | VAF 75/155 reads (48%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*4501G>T | 3'UTR (SNP) | VAF 65/156 reads (42%) | called by muse, mutect2, varscan2
- POU2F1 | c.*4451T>C | 3'UTR (SNP) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- PRSS12 | chr4:118279397 G>A | 3'Flank (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- PTER | c.*556G>T | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- PTPA | c.999+155C>A | Intron (SNP) | VAF 103/210 reads (49%) | called by muse, mutect2, varscan2
- RADX | c.1735-11A>C | Intron (SNP) | VAF 68/148 reads (46%) | called by muse, mutect2, varscan2
- RFTN2 | c.*864T>G | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- SLC22A15 | c.944+275C>A | Intron (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- SLC38A3 | c.*41C>G | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- SNORA71D | chr20:38433851 T>C | 3'Flank (SNP) | VAF 8/60 reads (13%) | catalogued as rs1176087631; called by muse, varscan2
- STK40 | c.*954G>T | 3'UTR (SNP) | VAF 9/268 reads (3%) | called by muse, mutect2
- SYBU | c.*379T>C | 3'UTR (SNP) | VAF 66/166 reads (40%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.*696G>A | 3'UTR (SNP) | VAF 195/431 reads (45%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+55112G>A | Intron (SNP) | VAF 68/141 reads (48%) | catalogued as rs1462617064; called by muse, mutect2, varscan2
- TCIM | c.*1078T>A | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- THBS2 | c.*708A>C | 3'UTR (SNP) | VAF 66/151 reads (44%) | called by muse, mutect2, varscan2
- TPT1 | c.102+112A>G | Intron (SNP) | VAF 91/97 reads (94%) | called by muse, mutect2, varscan2
- UBE2J1 | c.*2444_*2446del | 3'UTR (DEL) | VAF 40/83 reads (48%) | called by pindel, varscan2
- UTS2 | chr1:7853486 C>T | 5'Flank (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- VSTM2A | c.*118C>A | 3'UTR (SNP) | VAF 183/447 reads (41%) | called by muse, mutect2, varscan2
- WWC3 | c.*1244C>G | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- ZNRF3 | c.*3775T>C | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
